Somatic mutation profile of tumor specimen C3N-00729-02 (aliquot CPT0064930010) from CPTAC case C3N-00729, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IB; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 86.3 years (31,527 days).
Specimen C3N-00729-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1ea7fe0-90ce-4fec-8f3c-8a9b02b4045a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00729-31 (Blood Derived Normal), aliquot CPT0070650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82bb380c-94ec-4784-8b0a-f78ffa8b0b2d

The open-access MAF lists 94 somatic variants for this specimen: 68 protein-altering or splice-affecting, 16 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 16, RNA 4, 5'Flank 4, Frame Shift Ins 2, Splice Region 2, In Frame Del 2, Frame Shift Del 2, 3'UTR 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.1124A>G p.Y375C | Missense Mutation (SNP) | VAF 626/851 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs121913478, CM960653, COSV60640350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1384_1395del p.E462_R465del (on ENST00000521381 / NM_181523.3; = p.E192_R195del on NM_181504.4) | In Frame Del (DEL) | VAF 8/49 reads (16%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 18/34 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs587780004, COSV100911304, COSV64289791; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACKR3 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); catalogued as rs747331262, COSV56020531; called by muse, mutect2, varscan2
- AKAP13 | c.6685C>T p.R2229W (on ENST00000394518 / NM_007200.5; = p.R2233W on NM_006738.6) | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199748104; called by muse, mutect2, varscan2
- CACNA1D | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 89/497 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs914971602; called by muse, mutect2, varscan2
- CEP89 | c.169C>G p.L57V | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99992997; called by muse, mutect2, varscan2
- COL7A1 | c.3107G>A p.R1036Q | Missense Mutation (SNP) | VAF 43/654 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs150873722, COSV100096408; called by muse, mutect2
- ERN2 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 77/305 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs780525550; called by muse, mutect2, varscan2
- FKBP1C | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 109/571 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1462133713, COSV62179062; called by muse, mutect2, varscan2
- GALNT9 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 54/304 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs532514523; called by muse, mutect2, varscan2
- GRID2 | c.2776C>T p.H926Y | Missense Mutation (SNP) | VAF 61/309 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV99948473; called by muse, mutect2, varscan2
- GRIN2A | c.3433G>A p.V1145M | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as rs779746293, COSV58025654; called by muse, mutect2, varscan2
- IHO1 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 70/340 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs760328680; called by muse, mutect2, varscan2
- INPP5E | c.1372T>C p.Y458H | Missense Mutation (SNP) | VAF 72/1120 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV65497407; called by muse, mutect2
- KEAP1 | c.1808G>T p.G603V | Missense Mutation (SNP) | VAF 119/279 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50261740; called by muse, mutect2, varscan2
- KRT34 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 118/524 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as rs1239097466, COSV67449453; called by muse, mutect2, varscan2
- LACTB | c.1242del p.M414Ifs*29 | Frame Shift Del (DEL) | VAF 8/120 reads (7%) | catalogued as COSV56056337; called by mutect2, pindel
- LGALS9C | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 87/378 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs779017810; called by muse, mutect2, varscan2
- MAMDC4 | c.2806G>A p.E936K (on ENST00000445819; = p.E857K on NM_206920.3) | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.097); catalogued as rs564039894; called by muse, mutect2, varscan2
- MGAM | c.4529G>A p.R1510H | Missense Mutation (SNP) | VAF 101/429 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760340491, COSV72075067; called by muse, mutect2, varscan2
- MINAR1 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs371906868; called by muse, mutect2
- MRGPRX3 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs373134264; called by muse, mutect2, varscan2
- NLGN3 | c.2258C>T p.P753L (on ENST00000358741 / NM_181303.2; = p.P733L on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs1230310050, COSV100705051; called by muse, mutect2, varscan2
- OR10K2 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 24/572 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.21); catalogued as rs1031316708; called by muse, mutect2
- PLXNB2 | c.3136G>C p.V1046L | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.02); catalogued as COSV63781428; called by muse, mutect2, varscan2
- PRICKLE1 | c.1969C>T p.R657W | Missense Mutation (SNP) | VAF 123/418 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV58206376; called by muse, mutect2, varscan2
- SAPCD2 | c.950del p.P317Rfs*11 | Frame Shift Del (DEL) | VAF 37/216 reads (17%) | catalogued as COSV68836883; called by mutect2, pindel
- STAG2 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as COSV54354995; called by muse, mutect2
- TBC1D16 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs556223947; called by muse, mutect2, varscan2
- TEAD4 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 63/238 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs555272304; called by muse, mutect2, varscan2
- TRPM1 | c.3380G>A p.R1127H | Missense Mutation (SNP) | VAF 80/405 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs1339951481; called by muse, mutect2, varscan2
- TRPM4 | c.3302C>T p.P1101L | Missense Mutation (SNP) | VAF 103/359 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs774531670, COSV53267389; called by muse, mutect2, varscan2
- VPS52 | c.1952C>T p.S651L | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV101408765; called by muse, mutect2, varscan2
- ZSCAN10 | c.1739G>A p.R580H (on ENST00000252463; = p.R635H on NM_032805.3) | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as rs1430087984; called by muse, mutect2, varscan2
- ADAMTS16 | c.1306G>T p.G436* | Nonsense Mutation (SNP) | VAF 25/109 reads (23%) | called by muse, mutect2
- AHNAK | c.17039_17062del p.V5680_A5687del | In Frame Del (DEL) | VAF 76/380 reads (20%) | called by mutect2, pindel
- ANKRD28 | c.2110G>T p.A704S | Missense Mutation (SNP) | VAF 108/401 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- BRD1 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 65/320 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- C11orf96 | c.161T>G p.L54W | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2, varscan2
- CAD | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CKAP2L | c.1759-7C>A | Splice Region (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- DHX40 | c.1096G>C p.V366L | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- DNAH1 | c.4052C>T p.P1351L | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EVL | c.491T>G p.L164R (on ENST00000402714 / NM_001330221.2; = p.L166R on NM_016337.3) | Missense Mutation (SNP) | VAF 15/359 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.296); called by muse, mutect2
- EZR | c.713T>C p.I238T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.715); called by muse, mutect2
- FAM20A | c.404+1G>C p.X135_splice | Splice Site (SNP) | VAF 35/164 reads (21%) | called by muse, mutect2, varscan2
- HMX3 | c.358T>A p.Y120N | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); called by muse, varscan2
- IGHV3-15 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 82/341 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- INAVA | c.1754T>C p.V585A | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KATNIP | c.1285A>G p.R429G | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- KLB | c.1108T>C p.F370L | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC24 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYO1G | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- NAA15 | c.996dup p.Y333Ifs*18 | Frame Shift Ins (INS) | VAF 9/33 reads (27%) | called by mutect2, pindel
- NID1 | c.3338G>T p.G1113V | Missense Mutation (SNP) | VAF 59/374 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPCML | c.917A>C p.N306T | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RBP3 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 66/342 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- REN | c.110A>G p.K37R | Missense Mutation (SNP) | VAF 205/618 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- RERE | c.4112dup p.N1372Efs*23 | Frame Shift Ins (INS) | VAF 28/93 reads (30%) | called by mutect2, pindel, varscan2
- SEMA5B | c.1688G>A p.G563E | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SOX17 | c.238A>G p.K80E | Missense Mutation (SNP) | VAF 93/471 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STOX1 | c.731G>T p.C244F | Missense Mutation (SNP) | VAF 90/288 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF1 | c.3632T>A p.L1211Q (on ENST00000373790 / NM_138923.4; = p.L1232Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TMEM33 | c.399A>G p.A133= | Splice Region (SNP) | VAF 23/113 reads (20%) | called by muse, mutect2, varscan2
- WDR48 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 65/312 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF480 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF646 | c.622A>C p.S208R | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2
- ANKRD23 | c.606G>A p.R202= | Silent (SNP) | VAF 62/356 reads (17%) | catalogued as rs750811588; called by muse, mutect2, varscan2
- DMXL2 | c.33C>T p.V11= | Silent (SNP) | VAF 36/210 reads (17%) | catalogued as rs887564303, COSV51847013, COSV99196213; called by muse, mutect2, varscan2
- EIF4G1 | c.2679G>A p.R893= (on ENST00000346169 / NM_198241.3; = p.R698= on NM_004953.5) | Silent (SNP) | VAF 168/440 reads (38%) | catalogued as rs755577826, COSV59992734; called by muse, mutect2, varscan2
- FLG | c.1230C>T p.S410= | Silent (SNP) | VAF 310/748 reads (41%) | catalogued as rs766436341, COSV64238982; called by muse, mutect2, varscan2
- FRYL | c.4818C>T p.L1606= | Silent (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- GPS1 | c.1317T>C p.S439= | Silent (SNP) | VAF 70/534 reads (13%) | called by muse, mutect2, varscan2
- HDAC3 | c.670C>A p.R224= | Silent (SNP) | VAF 61/269 reads (23%) | called by muse, mutect2, varscan2
- HTR2B | c.369C>T p.L123= | Silent (SNP) | VAF 62/233 reads (27%) | catalogued as COSV99295289; called by muse, mutect2, varscan2
- IFI6 | c.393G>A p.*131= | Silent (SNP) | VAF 51/130 reads (39%) | called by muse, mutect2, varscan2
- ISM1 | c.555C>T p.D185= | Silent (SNP) | VAF 86/394 reads (22%) | catalogued as rs377766422; called by muse, mutect2, varscan2
- LRRC41 | c.2071C>T p.L691= | Silent (SNP) | VAF 142/449 reads (32%) | called by muse, mutect2, varscan2
- MAST3 | c.3588G>A p.A1196= | Silent (SNP) | VAF 46/117 reads (39%) | catalogued as rs768502140; called by muse, mutect2, varscan2
- NFASC | c.1302G>A p.S434= (on ENST00000339876 / NM_001378329.1; = p.S445= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 149/343 reads (43%) | catalogued as rs750856686, COSV58361811; called by muse, mutect2, varscan2
- OBSCN | c.13173C>T p.F4391= | Silent (SNP) | VAF 140/406 reads (34%) | catalogued as rs748377121, COSV52777625; called by muse, mutect2, varscan2
- PCDHA12 | c.486C>T p.I162= | Silent (SNP) | VAF 135/328 reads (41%) | catalogued as rs1312300687, COSV56476173; called by muse, mutect2, varscan2
- TAF1 | c.3633G>T p.L1211= (on ENST00000373790 / NM_138923.4; = p.L1232= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/144 reads (22%) | called by muse, mutect2, varscan2
- AC097518.1 | n.66C>T | RNA (SNP) | VAF 29/156 reads (19%) | catalogued as rs1485986653; called by muse, mutect2, varscan2
- AL590867.2 | n.52C>G | RNA (SNP) | VAF 72/490 reads (15%) | catalogued as rs375853555; called by muse, varscan2
- ATL3 | chr11:63671418 G>C | 5'Flank (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- CCDC105 | chr19:15010485 C>T | 5'Flank (SNP) | VAF 31/193 reads (16%) | catalogued as rs1040869908; called by muse, mutect2, varscan2
- CCNQ | c.*78C>T | 3'UTR (SNP) | VAF 91/390 reads (23%) | catalogued as rs182984949; called by muse, mutect2, varscan2
- CHCHD2P9 | n.32G>A | RNA (SNP) | VAF 38/183 reads (21%) | catalogued as rs373756242; called by muse, mutect2, varscan2
- RN7SL319P | chr15:75780354 G>A | 5'Flank (SNP) | VAF 118/529 reads (22%) | called by muse, mutect2, varscan2
- SCN4B | c.*2288C>T | 3'UTR (SNP) | VAF 49/215 reads (23%) | catalogued as rs1208102588; called by muse, mutect2, varscan2
- SYCE1 | chr10:133568078 C>T | 5'Flank (SNP) | VAF 17/42 reads (40%) | catalogued as rs769867649, COSV58219466; called by muse, mutect2, varscan2
- TUBB8P7 | n.1662C>T | RNA (SNP) | VAF 127/453 reads (28%) | catalogued as rs767143888; called by muse, varscan2
